Somatic mutation profile of tumor specimen ER-ADBL-TTM1-A (aliquot ER-ADBL-TTM1-A-2-0-D-A503-34) from EXCEPTIONAL_RESPONDERS case ER-ADBL, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Melanoma, NOS; Tissue or organ of origin: Skin of lower limb and hip; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.7 years (23,981 days).
Specimen ER-ADBL-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecc74ebb-d6df-46aa-92ee-671044d85f94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADBL-NT1-A (Solid Tissue Normal), aliquot ER-ADBL-NT1-A-2-0-D-A503-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/159e7645-4df7-4bb5-9f07-3e2ee337ca14

The open-access MAF lists 1,121 somatic variants for this specimen: 675 protein-altering or splice-affecting, 357 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 618, Silent 357, Nonsense Mutation 36, 3'UTR 27, Intron 21, RNA 18, 5'UTR 14, Splice Region 13, Splice Site 6, 5'Flank 6, 3'Flank 3, Frame Shift Del 1.

Variants (750 of 1,121; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as rs1564930625, COSV61084152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP7B1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 65/187 reads (35%) | catalogued as rs886041525, COSV100042075, COSV59592380; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MPZ | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.845); catalogued as rs281865123, CM994407; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907923, CM031316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ROCK1 | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 107/475 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520015, COSV67699520; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 40/71 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOD1 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs766355759; called by muse, mutect2, varscan2
- ACTRT2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.272); catalogued as COSV65759593; called by muse, mutect2
- ADAM7 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51537863; called by muse, mutect2, varscan2
- ADAMTS9 | c.2908G>A p.G970R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs1166611461; called by muse, mutect2, varscan2
- ADARB2 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV67231722; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- ADH1B | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs953630325, COSV99043340; called by muse, mutect2, varscan2
- AKAP13 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV63447826; called by muse, mutect2, varscan2
- AL645922.1 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54959939; called by muse, mutect2, varscan2
- ALPK3 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV51931373; called by muse, mutect2, varscan2
- ALX3 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as rs1036273636, COSV63928822; called by muse, mutect2, varscan2
- AMPH | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.928); catalogued as COSV57743924; called by muse, mutect2, varscan2
- ARHGAP6 | c.2387G>A p.G796E (on ENST00000337414 / NM_013427.3; = p.G593E on NM_013423.3) | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.014); catalogued as rs751151054; called by muse, mutect2, varscan2
- ASPN | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201992263; called by muse, mutect2, varscan2
- ASTN1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); catalogued as rs751328825; called by muse, mutect2, varscan2
- ASZ1 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52914693, COSV99497734; called by muse, mutect2, varscan2
- ATP10D | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV56710677; called by muse, mutect2, varscan2
- ATP11A | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs776288306, COSV52115034; called by muse, mutect2, varscan2
- ATP9A | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs267605994, COSV58764247; called by muse, mutect2, varscan2
- ATXN7L1 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs372907550; called by muse, mutect2, varscan2
- AZU1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs781271870; called by muse, mutect2
- BCAS1 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.058); catalogued as COSV65088257; called by muse, mutect2, varscan2
- BCOR | c.3613C>T p.P1205S (on ENST00000378444 / NM_001123385.2; = p.P1171S on NM_017745.6) | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV60707167; called by muse, mutect2, varscan2
- BROX | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs866989832, COSV61799953; called by muse, mutect2, varscan2
- C19orf44 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs752485439, COSV55614180; called by muse, mutect2, varscan2
- C20orf194 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99330374; called by muse, mutect2, varscan2
- C3 | c.4595G>C p.R1532P | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55576547, COSV99836008; called by muse, varscan2
- CACNA1B | c.948G>A p.W316* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as rs1554925946, COSV99500986; called by muse, mutect2, varscan2
- CACNA1E | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.104); catalogued as rs186600513; called by muse, mutect2, varscan2
- CACNG7 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55817780; called by muse, mutect2, varscan2
- CADM3 | c.245G>A p.R82Q (on ENST00000368125 / NM_001127173.3; = p.R116Q on NM_021189.5) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63684047, COSV63685846; called by muse, mutect2, varscan2
- CADPS2 | c.2738G>A p.R913Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs866025011, COSV100466546; called by muse, mutect2, varscan2
- CATSPERB | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866512933, COSV56426913; called by muse, mutect2, varscan2
- CBFA2T2 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs758482628, COSV60800290; called by muse, mutect2, varscan2
- CCM2L | c.1163G>A p.C388Y (on ENST00000452892 / NM_001365692.1; = p.V367I on NM_080625.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1273249449; called by muse, mutect2, varscan2
- CD1C | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV63806121; called by muse, mutect2, varscan2
- CD300E | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV60789798; called by muse, mutect2, varscan2
- CD6 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV57839798; called by muse, mutect2, varscan2
- CDC73 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 142/324 reads (44%) | catalogued as CM032945, COSV66467551, COSV66468296; called by muse, mutect2, varscan2
- CDH10 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1030268503, COSV52574741; called by muse, mutect2, varscan2
- CDH10 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52579683, COSV52599865; called by muse, mutect2, varscan2
- CDH17 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs1390706162; called by muse, mutect2, varscan2
- CDH18 | c.1766G>C p.C589S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56908106; called by muse, mutect2, varscan2
- CDH22 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV64836596; called by muse, mutect2
- CDH4 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922235979; called by muse, mutect2, varscan2
- CEP112 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as rs751353344, COSV67138475; called by muse, mutect2, varscan2
- CEP164 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1408428826; called by muse, mutect2, varscan2
- CEP290 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 97/253 reads (38%) | catalogued as COSV58349184; called by muse, mutect2, varscan2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 136/308 reads (44%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2, varscan2
- CFAP61 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55620911; called by muse, mutect2, varscan2
- CFHR2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753517273, COSV66380522; called by muse, mutect2, varscan2
- CFHR5 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.06); catalogued as COSV56829640; called by muse, mutect2, varscan2
- CHAF1A | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as rs573496948; called by muse, mutect2, varscan2
- CNTN5 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757785890, COSV54352345; called by muse, mutect2, varscan2
- COL10A1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54573216; called by muse, mutect2, varscan2
- COL11A1 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 192/401 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62199330; called by muse, mutect2, varscan2
- COL1A2 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.162); catalogued as rs267601643, COSV51956174; called by muse, mutect2, varscan2
- COL22A1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1361402047; called by muse, varscan2
- COL4A1 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753989899, COSV65433356; called by muse, mutect2, varscan2
- COLEC10 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as rs780599346; called by muse, mutect2, varscan2
- CPNE5 | c.1201-1G>A p.X401_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as rs1448791253; called by muse, mutect2
- CR1 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775760258; called by muse, mutect2, varscan2
- CRB1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs368152306, CM058356, COSV66328803; called by muse, mutect2, varscan2
- CSF2RA | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs764272709, COSV62625370; called by muse, mutect2, varscan2
- CSF2RB | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV53256731; called by muse, mutect2, varscan2
- CSMD1 | c.5816C>T p.S1939F (on ENST00000520002; = p.S1938F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930117621, COSV59282134; called by muse, mutect2, varscan2
- CSMD1 | c.2345C>T p.S782F (on ENST00000520002; = p.S781F on NM_033225.6) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59294145; called by muse, mutect2, varscan2
- CSMD3 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as COSV52231993; called by muse, mutect2, varscan2
- CYP11B2 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.107); catalogued as rs1309334971; called by muse, mutect2, varscan2
- CYP2C18 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53669658; called by muse, mutect2, varscan2
- CYP3A7 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV60481864; called by muse, mutect2, varscan2
- DCANP1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs376193776; called by muse, mutect2, varscan2
- DCX | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 175/276 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs727503897, COSV100576494, COSV57567054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDO | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64469738; called by muse, mutect2, varscan2
- DLGAP2 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.988); catalogued as rs148182252; called by muse, mutect2, varscan2
- DLGAP2 | c.2847G>A p.W949* | Nonsense Mutation (SNP) | VAF 39/129 reads (30%) | catalogued as COSV70098715; called by muse, mutect2, varscan2
- DNAH11 | c.4622G>A p.R1541Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs780372134, COSV60942462; called by muse, mutect2, varscan2
- DNAH8 | c.11552G>A p.G3851E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs959738768; called by muse, mutect2, varscan2
- DOCK2 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs767485999; called by muse, mutect2, varscan2
- DPPA4 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59512750; called by muse, mutect2, varscan2
- DSCAM | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.67); catalogued as rs572529984, COSV68031412; called by muse, mutect2, varscan2
- DUS2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs560287191; called by muse, mutect2, varscan2
- EDARADD | c.154C>T p.P52S (on ENST00000334232 / NM_145861.4; = p.P42S on NM_080738.4) | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1259703946, COSV100512600; called by muse, mutect2, varscan2
- EGFLAM | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59293092; called by muse, mutect2, varscan2
- EGFR | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51794983; called by muse, mutect2, varscan2
- ELAPOR2 | c.1565C>T p.S522L (on ENST00000450689 / NM_001142749.3; = p.S355L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs200295149; called by muse, mutect2, varscan2
- ELOA2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55295940; called by muse, mutect2, varscan2
- EPG5 | c.3917C>T p.P1306L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs534935599, COSV56350201; called by muse, mutect2, varscan2
- EPHA1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753358941; called by muse, mutect2, varscan2
- ESRP2 | c.1117G>A p.D373N (on ENST00000565858 / NM_001365264.1; = p.D363N on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs776765965; called by muse, mutect2, varscan2
- EVX1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs1240421820; called by muse, mutect2, varscan2
- FABP1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.733); catalogued as COSV55558894; called by muse, mutect2, varscan2
- FAM193B | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs747110286, COSV61557495; called by muse, mutect2, varscan2
- FAM209B | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs140276541, COSV100990998, COSV64915329; called by muse, mutect2
- FAM81B | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs148381850, COSV51986553; called by muse, mutect2, varscan2
- FAM83C | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100981567; called by muse, mutect2, varscan2
- FANCI | c.157+8T>A | Splice Region (SNP) | VAF 20/42 reads (48%) | catalogued as rs1567141408; called by muse, mutect2, varscan2
- FANK1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1564979238; called by muse, mutect2, varscan2
- FAT3 | c.13322C>T p.S4441F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV53172888; called by muse, mutect2, varscan2
- FCGR3B | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54209629; called by muse, varscan2
- FER1L6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67548489; called by muse, varscan2
- FERMT1 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs538697423, COSV54095137; called by muse, mutect2, varscan2
- FERMT1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs914756695; called by muse, mutect2, varscan2
- FGFR1 | c.995C>T p.S332F (on ENST00000447712 / NM_023110.3; = p.S330F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as CM070126, COSV58327622; called by muse, mutect2, varscan2
- FILIP1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV99386038; called by muse, mutect2, varscan2
- FLT3 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV54062516; called by muse, mutect2, varscan2
- FOSL2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as COSV53104328; called by muse, mutect2, varscan2
- FSCN3 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50001038; called by muse, mutect2, varscan2
- GAB1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV53754005; called by muse, mutect2, varscan2
- GABRA3 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs76218898; called by muse, mutect2, varscan2
- GABRE | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 37/61 reads (61%) | catalogued as COSV64819034; called by muse, mutect2, varscan2
- GAMT | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs866372100, COSV52038180; called by muse, mutect2, varscan2
- GBP7 | c.668G>T p.W223L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54008715; called by muse, mutect2, varscan2
- GJA10 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV101005331; called by muse, mutect2, varscan2
- GLI2 | c.2087C>T p.S696F (on ENST00000361492 / NM_001374353.1; = p.S713F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs865959844; called by muse, mutect2, varscan2
- GLIS1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV100390325; called by muse, mutect2, varscan2
- GLYATL3 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64592717; called by muse, mutect2, varscan2
- GPANK1 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367604820; called by muse, mutect2, varscan2
- GPR139 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1015377222, COSV58503087; called by muse, mutect2, varscan2
- GRID1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1476923699, COSV60023028, COSV60049340; called by muse, mutect2, varscan2
- GYS2 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV53923610; called by muse, mutect2, varscan2
- HEPH | c.2809G>A p.E937K (on ENST00000343002; = p.E670K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV57964914; called by muse, mutect2, varscan2
- HM13 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV59439313; called by muse, mutect2, varscan2
- HNRNPR | c.1181T>G p.M394R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs775988806; called by muse, mutect2, varscan2
- HS3ST2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1029443879, COSV54463649; called by muse, mutect2, varscan2
- HS3ST3A1 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs375811213; called by muse, mutect2, varscan2
- HSPA6 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs760084677, COSV59060796; called by muse, mutect2, varscan2
- HUS1B | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.347); catalogued as rs770495251; called by muse, mutect2, varscan2
- IGSF9 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV63639792; called by muse, mutect2, varscan2
- INCENP | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767877684; called by muse, mutect2, varscan2
- INHBB | c.896G>C p.R299P | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV54677608; called by muse, mutect2, varscan2
- INMT-MINDY4 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.81); catalogued as rs1360436346; called by muse, mutect2, varscan2
- INPP5D | c.2968G>A p.E990K (on ENST00000445964 / NM_001017915.3; = p.E989K on NM_005541.5) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs1328261354; called by muse, mutect2, varscan2
- INSRR | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV63877676; called by muse, mutect2, varscan2
- IPO11 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs771818177, COSV57580780; called by muse, mutect2, varscan2
- ITPR3 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV65414386; called by muse, mutect2, varscan2
- KALRN | c.2921C>T p.A974V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as COSV99566730; called by muse, mutect2, varscan2
- KCNH2 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs199472947, CM099226, CM111008; ClinVar: not provided; called by muse, mutect2, varscan2
- KCNT2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV54062653; called by muse, mutect2, varscan2
- KDF1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.463); catalogued as COSV57671152; called by muse, mutect2, varscan2
- KDM5B | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs142794881; called by muse, mutect2, varscan2
- KIAA2013 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.406); catalogued as rs1382887320; called by muse, mutect2, varscan2
- KIF2B | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52132166; called by muse, mutect2, varscan2
- KIF2B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV52131446; called by muse, mutect2, varscan2
- KLHL8 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.683); catalogued as rs1045657023; called by muse, mutect2, varscan2
- KPRP | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64221863; called by muse, mutect2, varscan2
- KRT72 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs376773990; called by muse, mutect2, varscan2
- LAG3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs753466689; called by muse, mutect2, varscan2
- LAMA1 | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767646512; called by muse, mutect2, varscan2
- LAMA2 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV70343366; called by muse, mutect2, varscan2
- LAMA5 | c.4919C>T p.S1640L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs199963174; called by muse, mutect2, varscan2
- LATS2 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs753049071; called by muse, mutect2, varscan2
- LATS2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs758975100; called by muse, mutect2, varscan2
- LCE6A | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.432); catalogued as rs1246023365; called by muse, mutect2, varscan2
- LCK | c.1431G>A p.W477* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV60739154; called by muse, mutect2, varscan2
- LGSN | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs748439660, COSV65726386; called by muse, mutect2, varscan2
- LIG4 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63596641; called by muse, mutect2, varscan2
- LMNA | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100738700; called by muse, mutect2, varscan2
- LPAR3 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748520381; called by muse, mutect2, varscan2
- LRIT3 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as COSV59986419; called by muse, mutect2, varscan2
- LRRD1 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1445693554; called by muse, mutect2, varscan2
- LRRD1 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1282979712; called by muse, mutect2, varscan2
- MACF1 | c.21934C>T p.R7312W (on ENST00000372915; = p.R5357W on NM_012090.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs143755803; called by muse, varscan2
- MAP3K5 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62892263; called by muse, mutect2, varscan2
- MAST1 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52247100; called by muse, mutect2, varscan2
- MCF2L2 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs143903251, COSV61049587; called by muse, mutect2, varscan2
- MCM9 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.23); catalogued as COSV100309636; called by muse, mutect2, varscan2
- MDFI | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1195031001; called by muse, mutect2
- MDFIC | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 55/189 reads (29%) | catalogued as COSV57568017; called by muse, mutect2, varscan2
- MDN1 | c.16310C>T p.P5437L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101021769; called by muse, mutect2, varscan2
- MGAM | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs782679232; called by muse, mutect2, varscan2
- MIB2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879095175; called by muse, mutect2, varscan2
- MIOX | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766169332, COSV99326821; called by muse, mutect2, varscan2
- MORC1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as rs746239411, COSV51717426, COSV51725283; called by muse, mutect2, varscan2
- MOXD1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as rs1286558079, COSV60948979; called by muse, mutect2, varscan2
- MPO | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51857572, COSV99228361; called by muse, mutect2, varscan2
- MPP6 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1290964278, COSV99757858, COSV99757912; called by muse, mutect2, varscan2
- MTMR9 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs267601726; called by muse, mutect2, varscan2
- MUC16 | c.33935C>T p.S11312L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as rs1398617429, COSV101199595; called by muse, mutect2, varscan2
- MUC16 | c.24904C>T p.P8302S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as rs1431974636, COSV67461200; called by muse, mutect2, varscan2
- MUC16 | c.10850C>T p.S3617L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1354215725, COSV67472521; called by muse, mutect2, varscan2
- MUC16 | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.763); catalogued as rs769830116, COSV67454358; called by muse, mutect2, varscan2
- MUC17 | c.9787C>T p.P3263S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60295432; called by muse, mutect2, varscan2
- MUC17 | c.12499G>A p.E4167K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs531240466; called by muse, mutect2, varscan2
- MUC4 | c.7405G>A p.D2469N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.55); catalogued as rs746633292; called by muse, mutect2
- MUC7 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59217196; called by muse, mutect2, varscan2
- MXRA5 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 30/53 reads (57%) | catalogued as rs779478362; called by muse, mutect2, varscan2
- MYCT1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs759084346, COSV65891392, COSV65891469; called by muse, mutect2, varscan2
- MYH1 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV56844122; called by muse, mutect2, varscan2
- MYH8 | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs770808142; called by muse, varscan2
- MYO15A | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs764932189, COSV52759987; called by muse, mutect2, varscan2
- MYO18B | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs779264183, COSV59149504; called by muse, mutect2, varscan2
- MYOCD | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs138967735, COSV58509440; called by muse, mutect2, varscan2
- MYT1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1452877732; called by muse, mutect2, varscan2
- NAF1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 124/454 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs549746195; called by muse, mutect2, varscan2
- NCAN | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776772645; called by muse, mutect2, varscan2
- NFS1 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65053909; called by muse, mutect2, varscan2
- NLRP1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs200160045; called by muse, mutect2, varscan2
- NOTCH2 | c.6130C>T p.R2044C | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221302379, COSV56697409; called by muse, mutect2, varscan2
- NPY2R | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs1252325263, COSV61528778; called by muse, mutect2, varscan2
- NR5A2 | c.848C>T p.S283F (on ENST00000367362 / NM_205860.3; = p.S237F on NM_003822.5) | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as rs763405171; called by muse, mutect2, varscan2
- NRG3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs564020344, COSV64551383; called by muse, mutect2, varscan2
- NRP1 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1221143595; called by muse, mutect2, varscan2
- NUP210 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs866421163; called by muse, mutect2
- NXPH1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68314477; called by muse, mutect2, varscan2
- OBSCN | c.3037G>A p.V1013M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs889925830; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by mutect2, varscan2
- OR4K5 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV60003852; called by muse, mutect2, varscan2
- OR51G2 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs150566249; called by muse, mutect2, varscan2
- OR5D14 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV59455892; called by muse, mutect2, varscan2
- OR5J2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1349697910, COSV56621998; called by muse, mutect2, varscan2
- OR5K1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60304057; called by muse, mutect2, varscan2
- OR6C4 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); catalogued as COSV67792773; called by muse, mutect2, varscan2
- OR9A4 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71885188; called by muse, mutect2, varscan2
- PAN3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as rs754349908; called by muse, mutect2, varscan2
- PAPPA2 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV100867457; called by muse, mutect2, varscan2
- PASD1 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV64855689; called by muse, mutect2, varscan2
- PCDH15 | c.5009C>T p.S1670L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.045); catalogued as COSV104411492; called by muse, mutect2, varscan2
- PCDHA3 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.31); catalogued as COSV63538847; called by muse, mutect2, varscan2
- PCDHB9 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs781934609, COSV53381274; called by muse, mutect2, varscan2
- PCLO | c.9425C>T p.S3142L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs868457640, COSV61656328; called by muse, mutect2, varscan2
- PCLO | c.6794C>T p.S2265F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs1185436297, COSV61621473; called by muse, mutect2, varscan2
- PCLO | c.5147G>A p.G1716E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs773335012, COSV61613244, COSV61665175; called by muse, mutect2, varscan2
- PCSK1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60737025; called by muse, mutect2, varscan2
- PGBD1 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as COSV52551367; called by muse, mutect2, varscan2
- PGGHG | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1380197600; called by muse, mutect2, varscan2
- PKHD1L1 | c.4307G>A p.G1436E | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs866923343, COSV65743016; called by muse, mutect2, varscan2
- PLA2G3 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749719925; called by muse, mutect2, varscan2
- PLCB4 | c.2119-1G>A p.X707_splice | Splice Site (SNP) | VAF 10/64 reads (16%) | catalogued as rs6118602; called by muse, mutect2, varscan2
- PLCG2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as rs1337238313; called by muse, mutect2, varscan2
- PLCH2 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV53942749; called by muse, mutect2, varscan2
- PLCL2 | c.2938C>T p.L980F (on ENST00000615277 / NM_001144382.2; = p.L854F on NM_015184.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV67620971; called by muse, mutect2
- PLPPR1 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1208537784; called by muse, mutect2, varscan2
- PLXNA1 | c.4277C>T p.P1426L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99302544; called by muse, mutect2, varscan2
- PLXNA4 | c.3657G>A p.M1219I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100326753; called by muse, mutect2
- PNLIPRP3 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768796683; called by muse, mutect2, varscan2
- POM121L2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.383); catalogued as COSV66276116, COSV66277023; called by muse, mutect2, varscan2
- PREX2 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99907806; called by muse, mutect2, varscan2
- PREX2 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs866534903, COSV55770593; called by muse, mutect2, varscan2
- PROX1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as COSV54784441; called by muse, mutect2, varscan2
- PRSS58 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs147205406; called by muse, mutect2, varscan2
- PTPN20 | c.918C>T p.S306= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs1240630047; called by mutect2, varscan2
- PTPRB | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54232063; called by muse, mutect2, varscan2
- PTPRD | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV61937304; called by muse, mutect2, varscan2
- PTPRQ | c.5813G>A p.G1938E (on ENST00000616559; = p.G1896E on NM_001145026.2) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs145711051, COSV57058290; called by muse, mutect2, varscan2
- PTPRT | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs724159843, COSV61963674; called by muse, mutect2, varscan2
- PYHIN1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.401); catalogued as COSV63723554; called by muse, mutect2, varscan2
- RAPGEF5 | c.870G>A p.Q290= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as rs1490731573, COSV59787856; called by muse, mutect2, varscan2
- REEP4 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762045119; called by muse, mutect2, varscan2
- RELN | c.5144C>T p.S1715L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58986995; called by muse, mutect2, varscan2
- RELN | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs757182615, COSV58997854; called by muse, mutect2, varscan2
- RERE | c.4333C>T p.H1445Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV61940867; called by muse, mutect2, varscan2
- REST | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV58359234; called by muse, mutect2, varscan2
- RGS12 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs751311594, COSV100123190; called by muse, mutect2, varscan2
- RGS4 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV63356821; called by muse, mutect2, varscan2
- RIMS4 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as rs375439986; called by muse, mutect2, varscan2
- RLN3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs139014638; called by muse, mutect2, varscan2
- ROBO1 | c.3379C>T p.R1127* | Nonsense Mutation (SNP) | VAF 54/104 reads (52%) | catalogued as rs765639480, COSV71391576; called by muse, mutect2, varscan2
- RPTN | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV60167761; called by muse, mutect2, varscan2
- RUNX1T1 | c.176C>T p.P59L (on ENST00000265814 / NM_001198628.1; = p.P32L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs552022984, COSV56154509; called by muse, varscan2
- S100A7L2 | c.196A>T p.K66* | Nonsense Mutation (SNP) | VAF 40/198 reads (20%) | catalogued as COSV64194866; called by muse, mutect2, varscan2
- SALL4 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV53853242; called by muse, mutect2
- SAMD14 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs201226333, COSV50305413; called by muse, mutect2, varscan2
- SCNN1B | c.1467G>A p.R489= | Splice Region (SNP) | VAF 33/87 reads (38%) | catalogued as COSV56310037; called by muse, mutect2, varscan2
- SCUBE1 | c.382T>C p.C128R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51814527; called by muse, mutect2, varscan2
- SEC31B | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760051385; called by muse, mutect2, varscan2
- SERPINA3 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555386065, COSV67586764; called by muse, mutect2, varscan2
- SERPINA7 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59666942; called by muse, mutect2, varscan2
- SERPINB3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52193036; called by muse, mutect2, varscan2
- SGCZ | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV101166432, COSV101168919; called by muse, mutect2, varscan2
- SIRPD | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs139039354, COSV67547239; called by muse, mutect2
- SLC25A52 | c.263G>A p.R88Q (on ENST00000672005; = p.R78Q on NM_001034172.4) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs865854821, COSV52501584; called by muse, mutect2, varscan2
- SLC39A4 | c.1390C>T p.P464S (on ENST00000301305 / NM_001374839.1; = p.P439S on NM_017767.3) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1040441696; called by muse, mutect2, varscan2
- SLC4A8 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV100177578; called by muse, mutect2, varscan2
- SLC6A5 | c.1373G>A p.W458* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV54224198; called by muse, mutect2, varscan2
- SLC9A4 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs150347528, COSV54840390; called by muse, mutect2, varscan2
- SLCO1C1 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs995142963, COSV99858839; called by muse, mutect2, varscan2
- SLITRK5 | c.2743G>A p.V915M | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1315343659; called by muse, mutect2, varscan2
- SORCS2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs747884144, COSV61162520; called by muse, mutect2, varscan2
- SORCS3 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV63795587; called by muse, mutect2, varscan2
- SOS2 | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.101); catalogued as rs1385319218; called by muse, mutect2, varscan2
- SPN | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1362822396, COSV64070149; called by muse, mutect2, varscan2
- SPTA1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598102, COSV100934909, COSV63755764; called by muse, mutect2, varscan2
- SPTLC3 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100983002; called by muse, mutect2, varscan2
- STRIP2 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); catalogued as COSV50806231; called by muse, mutect2, varscan2
- STXBP2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs371725400, COSV55405741; called by muse, mutect2, varscan2
- TAS2R40 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV68818385; called by muse, mutect2, varscan2
- TCAF2 | c.2542C>T p.L848F (on ENST00000441159 / NM_001363538.2; = p.L744F on NM_001130026.2) | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1563178751; called by muse, mutect2, varscan2
- TCL1A | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV101268458; called by muse, mutect2, varscan2
- TCN1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57252996; called by muse, mutect2, varscan2
- TCP10L2 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.188); catalogued as COSV52086952; called by muse, mutect2, varscan2
- TCP11L2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763401853, COSV54429024; called by muse, mutect2, varscan2
- TDRD5 | c.2401C>T p.L801F | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV54252000; called by muse, mutect2, varscan2
- TEX30 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as rs573603152, COSV101051943; called by muse, mutect2, varscan2
- TLL1 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 45/143 reads (31%) | catalogued as rs774503754; called by muse, mutect2, varscan2
- TMEM132A | c.3037C>T p.R1013C (on ENST00000453848 / NM_178031.3; = p.R1014C on NM_017870.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs749168270, COSV50001912; called by muse, mutect2, varscan2
- TMEM67 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV60037121; called by muse, mutect2, varscan2
- TNIP3 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV50249263; called by muse, mutect2, varscan2
- TNMD | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65976855; called by muse, mutect2, varscan2
- TPTE | c.1615G>A p.E539K (on ENST00000618007 / NM_199261.4; = p.E521K on NM_199259.4) | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs369994889; called by muse, mutect2, varscan2
- TRAM2 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs370828858; called by muse, mutect2, varscan2
- TRAPPC9 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758405220, COSV66895078; called by muse, mutect2, varscan2
- TSNAX | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 112/286 reads (39%) | catalogued as rs757155042; called by muse, mutect2, varscan2
- TTN | c.14456C>T p.S4819L (on ENST00000591111; = p.S3892L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | PolyPhen possibly damaging (0.452); catalogued as rs764310312, COSV59969202; called by muse, mutect2, varscan2
- TTN | c.12772G>A p.E4258K (on ENST00000591111; = p.E4212K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV60318393; called by muse, mutect2
- TTYH2 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53911751; called by muse, mutect2, varscan2
- TXNDC11 | c.2344G>A p.D782N (on ENST00000356957 / NM_001303447.2; = p.D755N on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs1247404662; called by muse, mutect2, varscan2
- UBQLN3 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV61163954; called by muse, mutect2, varscan2
- UBXN10 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV100907733; called by muse, mutect2, varscan2
- UBXN10 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100907736; called by muse, mutect2, varscan2
- UNC13C | c.5590G>A p.E1864K | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.981); catalogued as rs753934007, COSV52858100, COSV99523852; called by muse, mutect2, varscan2
- UNC5A | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs773919818, COSV56172508; called by muse, mutect2, varscan2
- USH1C | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV50018305; called by muse, mutect2
- VN1R2 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 23/37 reads (62%) | PolyPhen possibly damaging (0.608); catalogued as COSV59038497; called by muse, mutect2, varscan2
- VNN2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV58472512; called by muse, mutect2, varscan2
- VSIG4 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV66073754; called by muse, mutect2, varscan2
- WAC | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.3); catalogued as rs867622037, COSV100611070, COSV61568232; called by muse, mutect2, varscan2
- WASHC5 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 51/152 reads (34%) | catalogued as rs762363112; called by muse, mutect2, varscan2
- WIPF1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs376434194; called by muse, mutect2, varscan2
- WNT2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55411823; called by muse, mutect2, varscan2
- ZFHX4 | c.6832C>T p.R2278C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50641875; called by muse, mutect2, varscan2
- ZFP57 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM083211, COSV100971923; called by muse, mutect2, varscan2
- ZNF148 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.247); catalogued as rs774113521; called by muse, mutect2, varscan2
- ZNF169 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100566341; called by muse, mutect2, varscan2
- ZNF208 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.254); catalogued as rs1274331979, COSV68100909; called by muse, varscan2
- ZNF469 | c.5737G>A p.E1913K (on ENST00000437464; = p.E1941K on NM_001367624.2) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.018); catalogued as rs867698235; called by muse, mutect2, varscan2
- ZNF516 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs747195084; called by muse, mutect2, varscan2
- ZNF536 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62831378; called by muse, mutect2, varscan2
- ZNF560 | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV56866901; called by muse, mutect2, varscan2
- ZNF684 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65519843; called by muse, mutect2, varscan2
- ZNF711 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 107/188 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52151091; called by muse, mutect2, varscan2
- ZNF804A | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.813); catalogued as COSV56477286; called by muse, mutect2, varscan2
- ZNF99 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs558219171, COSV68055465, COSV68055886, COSV68056062; called by muse, mutect2, varscan2
- ZPBP | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs559157574, COSV50431923; called by muse, mutect2, varscan2
- AC004922.1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM18 | c.1629G>A p.R543= | Splice Region (SNP) | VAF 51/142 reads (36%) | called by muse, mutect2, varscan2
- ADCY1 | c.1694T>C p.V565A | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, varscan2
- ADH1C | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHRR | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AKR1C2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALG13 | c.977A>C p.Y326S | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALOX12B | c.1958T>G p.F653C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ALPK2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AMPH | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ANK2 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ANKRD53 | c.733T>A p.Y245N | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- APOB | c.4603G>A p.G1535R | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARFGEF2 | c.5159C>T p.T1720I | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARFGEF3 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGEF11 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARHGEF2 | c.1367C>T p.P456L (on ENST00000361247 / NM_001162383.2; = p.P428L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARMC4 | c.2653C>T p.L885F | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ASB16 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASH1L | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ATP13A4 | c.3355T>G p.F1119V | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.611); called by muse, mutect2
- ATP1B1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- BBS12 | c.1219T>C p.F407L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BDKRB2 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BEND2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- BHMT | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTBD11 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- C1RL | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C1orf198 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- C3 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, varscan2
- CA12 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CACNA1A | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CALML3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CAMSAP2 | c.2648T>G p.L883* (on ENST00000236925 / NM_001297707.2; = p.L872* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- CAMSAP3 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CARMIL3 | c.3361G>A p.G1121S | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CATSPERB | c.2687G>A p.R896K | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC168 | c.13922C>T p.S4641L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- CCDC174 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CD5L | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP350 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CEP43 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- CFAP221 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CFH | c.3599T>G p.V1200G | Missense Mutation (SNP) | VAF 128/587 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CHAF1A | c.105C>T p.A35= | Splice Region (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- CHGB | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CHRNA4 | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CHRNB4 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHUK | c.1863_1865dup p.L622dup | In Frame Ins (INS) | VAF 31/67 reads (46%) | called by mutect2, pindel, varscan2
- CLCA2 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CLDN16 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CMKLR1 | c.853C>T p.H285Y (on ENST00000312143 / NM_001142344.2; = p.H283Y on NM_004072.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNGB1 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.183); called by muse, varscan2
- COL22A1 | c.4214G>A p.G1405E | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, varscan2
- COL5A3 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A5 | c.4790G>A p.G1597E | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CORIN | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRB2 | c.1463T>A p.L488* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- CRK | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CROCC | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSAG1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 136/240 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTAGE9 | c.1482G>C p.E494D | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CTNNA2 | c.2731C>T p.P911S (on ENST00000402739 / NM_001282597.3; = p.P863S on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA2 | c.2732C>T p.P911L (on ENST00000402739 / NM_001282597.3; = p.P863L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTSE | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP4F11 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CYSTM1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DCDC1 | c.4478G>A p.G1493E (on ENST00000597505 / NM_001367979.1; = p.G600E on NM_020869.3) | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); called by muse, varscan2
- DEF6 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DEFA3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- DGKG | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DGKZ | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH10 | c.12748G>A p.E4250K (on ENST00000409039; = p.E4189K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- DNAH5 | c.2146A>T p.I716F | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DNAH7 | c.10720G>A p.E3574K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DNAH9 | c.4275C>A p.D1425E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DNAH9 | c.6848G>A p.G2283E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNASE1L3 | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (1); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DNHD1 | c.11918T>C p.V3973A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK1 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DOCK2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- DOCK6 | c.1762-4C>T | Splice Region (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- DOP1B | c.2891T>C p.V964A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DSG2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, varscan2
- DUOX2 | c.2551T>G p.F851V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DYNC2H1 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EBF1 | c.1325A>G p.Q442R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- EBF2 | c.887T>G p.I296R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ELN | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ELOA2 | c.1768T>G p.F590V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EMID1 | c.102G>A p.R34= | Splice Region (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- EMILIN1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EML4 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTHD1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EPB42 | c.691C>T p.P231S (on ENST00000441366 / NM_001114134.2; = p.P261S on NM_000119.3) | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EPHA1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC2 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ESYT2 | c.573C>G p.D191E (on ENST00000613624; = p.D115E on NM_020728.3) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVPL | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- EXOC6 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- F5 | c.5552A>G p.E1851G | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- FAF1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- FAM160A1 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM160B2 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM161B | c.550C>T p.P184S (on ENST00000651776; = p.P121S on NM_152445.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FAM184B | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM221A | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 225/768 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARP1 | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASTKD5 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBN1 | c.4673C>T p.S1558F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FBP1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FBXO24 | c.482C>T p.A161V (on ENST00000241071 / NM_033506.3; = p.A199V on NM_012172.5) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FCAMR | c.1514C>T p.A505V (on ENST00000324852 / NM_001170631.2; = p.P238S on NM_032029.4) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FETUB | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FLII | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FMNL2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- FMO3 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FRMPD1 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FRMPD3 | c.4346C>T p.P1449L | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSHR | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FUT8 | c.934C>T p.L312F (on ENST00000360689 / NM_001371534.1; = p.L149F on NM_004480.4) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FZD8 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GAA | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- GAL3ST2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GATA5 | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GCM2 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCNT4 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMPR2 | c.70C>T p.L24F (on ENST00000355299 / NM_001351022.2; = p.L42F on NM_016576.5) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPR107 | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC6A | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRAMD1B | c.1385T>G p.V462G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- GRID2IP | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTPBP1 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HDGFL2 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGXB3 | c.4010C>T p.S1337F (on ENST00000613459; = p.S1091F on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HNF1B | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- HOXA11 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- IBTK | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- IGHV3-66 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- IGHV5-51 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF9 | c.1815G>A p.G605= (on ENST00000368094 / NM_001135050.2; = p.G589= on NM_020789.4) | Splice Region (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- IL12RB1 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- IL1R1 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INPP5E | c.1399A>T p.T467S | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INTS1 | c.3179C>A p.P1060H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ITSN2 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- JAKMIP1 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JCAD | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KALRN | c.3322C>T p.L1108F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KANK2 | c.1615C>T p.P539S (on ENST00000586659 / NM_001379562.1; = p.P547S on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNC3 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KCNH1 | c.636T>A p.H212Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH8 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ4 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ5 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KCTD15 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- KEL | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- KIAA1210 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- KIF2B | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- KIF4B | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- KLHL13 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, varscan2
- KRT37 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP5-3 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- KRTAP5-8 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LEPR | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 247/569 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGI2 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LINGO4 | c.1550C>T p.T517I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LMTK3 | c.4136G>A p.G1379E | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- LRP2 | c.2647C>G p.R883G | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC37A3 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- MAGEA8 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MAGEC1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, varscan2
- MBD1 | c.1003A>T p.N335Y (on ENST00000269468 / NM_001323950.1; = p.N312Y on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MCHR2 | c.779T>C p.F260S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- METTL24 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- METTL9 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MISP | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMP28 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC2 | c.4334G>A p.G1445E | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MST1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MUC16 | c.38555C>T p.P12852L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2
- MUC16 | c.19196C>T p.S6399F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MUC16 | c.10058G>A p.G3353E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MUC17 | c.10141C>T p.P3381S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MUC17 | c.12855G>A p.M4285I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- MUC4 | c.6706G>A p.G2236R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYH1 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, varscan2
- MYH2 | c.83A>C p.Q28P | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH8 | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | called by muse, varscan2
- MYO1E | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MYOG | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- NBEAL2 | c.5902C>A p.R1968S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- NCOR1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- NEFM | c.530A>T p.H177L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NEK1 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOMO2 | c.1921T>A p.C641S | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NOS2 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPNT | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.058); called by muse, varscan2
- NPS | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NPSR1 | c.120A>T p.E40D | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NRCAM | c.1089G>A p.W363* (on ENST00000379028 / NM_001371124.1; = p.W357* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- NT5E | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OBSCN | c.5360C>T p.A1787V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- OR10H3 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR51B5 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR7C1 | c.663T>G p.I221M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL3 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PBOV1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCDHA6 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 101/297 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PCDHB14 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDHB16 | c.251T>C p.L84S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- PCLO | c.6509C>T p.S2170L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PDCD2 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PHETA2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3CB | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PLEKHA7 | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- PLPPR3 | c.673G>A p.V225I (on ENST00000520876 / NM_001270366.2; = p.V253I on NM_024888.2) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXNA4 | c.3998C>T p.P1333L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L2 | c.3104A>G p.K1035R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POTEC | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- POU4F1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- PPIAL4A | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 111/275 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPP1R12B | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PPP1R3A | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRICKLE2 | c.2474T>G p.F825C (on ENST00000295902; = p.F769C on NM_198859.4) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PRICKLE2 | c.1745C>T p.S582F (on ENST00000295902; = p.S526F on NM_198859.4) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PRKAR2B | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PRKCSH | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PROSER1 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTK2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- PTPN20 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- PYDC2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- QRICH2 | c.3556T>C p.S1186P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- R3HDML | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RASAL2 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM47 | c.1513C>T p.P505S (on ENST00000295971 / NM_001098634.2; = p.P436S on NM_019027.4) | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.086); called by muse, varscan2
- RCVRN | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.8179G>A p.D2727N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF138 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- RNF39 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ROBO4 | c.810C>T p.V270= | Splice Region (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- RP1 | c.935T>A p.I312K | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RPS6KA6 | c.2046G>A p.W682* | Nonsense Mutation (SNP) | VAF 63/105 reads (60%) | called by muse, mutect2, varscan2
- RTL9 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR1 | c.3159G>T p.E1053D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.842); called by mutect2, varscan2
- SACS | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SALL2 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SAMD7 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- SAMHD1 | c.275+7A>C | Splice Region (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- SAMM50 | c.1241A>T p.H414L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SARDH | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SDCCAG8 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDK1 | c.3647G>A p.W1216* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- SDR16C5 | c.466-1G>A p.X156_splice | Splice Site (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
- SELENOI | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEPTIN2 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEPTIN6 | c.146-1G>A p.X49_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- SERPINB11 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 63/335 reads (19%) | called by muse, mutect2, varscan2
- SERPINB3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SERPINB5 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SERTAD4 | c.948T>A p.D316E | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SH2D4B | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHC3 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SIPA1L1 | c.4462A>G p.K1488E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SIRPD | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- SIRT7 | c.559C>G p.H187D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC13A5 | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- SLC15A3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SLC18B1 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- SLC24A3 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); called by muse, varscan2
- SLC25A42 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC38A1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SLC4A8 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- SLC6A4 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO2A1 | c.944T>A p.F315Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLFN11 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 98/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLITRK5 | c.2744T>A p.V915E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- SMYD3 | c.866C>T p.S289F (on ENST00000490107 / NM_001375962.1; = p.S230F on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SPHKAP | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPRR2F | c.146A>C p.Q49P | Missense Mutation (SNP) | VAF 22/75 reads (29%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN4 | c.3670G>A p.G1224S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.395); called by muse, varscan2
- SRPK3 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SRSF5 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRY | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- STAB1 | c.7037C>G p.A2346G | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- STIL | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- STK31 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SUGP2 | c.3142G>A p.E1048K | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SYNC | c.1359G>A p.K453= | Splice Region (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- SYNPO | c.2771C>T p.P924L (on ENST00000394243 / NM_001166208.2; = p.P680L on NM_001109974.3) | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF5L | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TBC1D16 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TBCD | c.2567T>A p.M856K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- TEX14 | c.4025-1G>A p.X1342_splice (on ENST00000240361 / NM_001201457.2; = p.X1296_splice on NM_031272.5) | Splice Site (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- TEX19 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THNSL1 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIPRL | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 217/487 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TMEM106B | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 242/804 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TNFRSF10D | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TNFSF15 | c.302-4C>T | Splice Region (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- TPTE | c.619C>T p.H207Y (on ENST00000618007 / NM_199261.4; = p.H189Y on NM_199259.4) | Missense Mutation (SNP) | VAF 63/381 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TRIM21 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRIM55 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TRIM65 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- TRIM72 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- TRPM2 | c.2315C>T p.S772F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TRPM6 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- UBR5 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UNC79 | c.7183C>T p.P2395S (on ENST00000393151 / NM_001346218.2; = p.P2218S on NM_020818.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USH1C | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2
- USP54 | c.4291C>T p.P1431S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- VMO1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- VWF | c.7106G>A p.R2369K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASHC5 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 157/539 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- YTHDC1 | c.1993C>T p.R665C (on ENST00000344157 / NM_001031732.4; = p.R647C on NM_133370.4) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YY1 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZAN | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB39 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ZFHX4 | c.10640C>T p.S3547F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZNF112 | c.2695C>T p.P899S (on ENST00000337401 / NM_001083335.2; = p.P893S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF112 | c.1309C>T p.H437Y (on ENST00000337401 / NM_001083335.2; = p.H431Y on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF346 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.5957C>T p.S1986F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZNF420 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF648 | c.404del p.L135* | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- ZSCAN21 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSCAN25 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ZZEF1 | c.7498C>T p.Q2500* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ABCC6 | c.1875G>A p.G625= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- ACOT11 | c.1128C>T p.S376= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs745659196, COSV59350660; called by muse, mutect2, varscan2
- ACP7 | c.402C>T p.P134= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as rs755025539, COSV58700101; called by muse, mutect2, varscan2
- ACSBG1 | c.1062C>T p.D354= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs745876684, COSV99357315; called by muse, mutect2, varscan2
- ACSBG2 | c.249C>T p.F83= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ADAM18 | c.1188G>A p.G396= | Silent (SNP) | VAF 74/248 reads (30%) | catalogued as COSV55845634; called by muse, mutect2, varscan2
- ADAM2 | c.273C>T p.F91= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV55860227; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2682G>A p.V894= | Silent (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- ADAR | c.2475C>T p.S825= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- ADARB1 | c.1179C>T p.C393= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV62342407; called by muse, mutect2, varscan2
- ADCY4 | c.2391C>T p.F797= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs770166725, COSV60257506; called by muse, mutect2, varscan2
- ADGRA1 | c.210C>T p.F70= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs751421975, COSV66925130; called by muse, mutect2, varscan2
- ADGRE5 | c.1392C>T p.F464= (on ENST00000242786 / NM_078481.4; = p.F371= on NM_001784.5) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs770027786; called by muse, mutect2, varscan2
- ADGRF5 | c.795C>T p.S265= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV51929606, COSV99346283; called by muse, varscan2
- ADGRG2 | c.429G>A p.T143= (on ENST00000379869 / NM_001079858.3; = p.T140= on NM_005756.4) | Silent (SNP) | VAF 86/158 reads (54%) | catalogued as COSV61341238; called by muse, varscan2
- AHCY | c.1155C>T p.F385= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV99464445; called by muse, mutect2, varscan2
- AHNAK2 | c.5007G>A p.G1669= | Silent (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- AHSP | c.147C>T p.I49= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56528829, COSV56528942; called by muse, mutect2, varscan2
- ALPK2 | c.4194C>T p.I1398= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV64493320; called by muse, mutect2, varscan2
- AMDHD2 | c.1026C>T p.F342= (on ENST00000293971 / NM_001330449.2; = p.F372= on NM_015944.4) | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs781177091; called by muse, mutect2, varscan2
- AMPD2 | c.612C>T p.S204= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- ANK3 | c.78G>A p.R26= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV55076560; called by muse, mutect2, varscan2
- ANO1 | c.1962G>A p.G654= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1304514350; called by muse, mutect2, varscan2
- ARAP2 | c.1953C>T p.I651= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as rs531576155; called by muse, mutect2, varscan2
- ARFGEF2 | c.4665C>T p.V1555= | Silent (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.3156C>T p.L1052= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs1055537912, COSV99292817; called by muse, mutect2, varscan2
- ARHGAP17 | c.327C>T p.S109= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.1755G>A p.R585= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- ARMC12 | c.1002C>T p.S334= (on ENST00000373866 / NM_001286574.2; = p.S361= on NM_145028.5) | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- ASCC2 | c.306C>T p.F102= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs200517344; called by mutect2, varscan2
- ASXL3 | c.4032C>T p.P1344= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- ATAT1 | c.906T>C p.P302= | Silent (SNP) | VAF 62/172 reads (36%) | called by muse, mutect2, varscan2
- ATP2A3 | c.360G>A p.K120= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- ATP8B3 | c.3768C>T p.H1256= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs752629834; called by muse, mutect2, varscan2
- AXDND1 | c.2868C>T p.T956= | Silent (SNP) | VAF 60/277 reads (22%) | called by muse, mutect2, varscan2
- AZU1 | c.492C>T p.S164= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs745794088; called by muse, mutect2
- B3GALT1 | c.267G>A p.K89= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- B4GALNT2 | c.381C>T p.S127= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1454236720; called by muse, mutect2
- BAIAP2 | c.1422C>T p.A474= | Silent (SNP) | VAF 72/264 reads (27%) | catalogued as rs752914362; called by muse, mutect2, varscan2
- BASP1 | c.90G>A p.A30= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs766697078, COSV59472688; called by muse, mutect2, varscan2
- BEND3 | c.699C>T p.P233= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- BEX5 | c.18G>A p.K6= | Silent (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- BRINP2 | c.1122G>A p.Q374= | Silent (SNP) | VAF 66/118 reads (56%) | called by muse, mutect2, varscan2
- BRINP2 | c.2274G>A p.R758= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV64175680; called by muse, mutect2, varscan2
- C1RL | c.273C>T p.S91= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- C1orf68 | c.198C>T p.T66= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs1281862363; called by muse, mutect2, varscan2
- C2 | c.636C>T p.F212= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- C7 | c.1506T>C p.G502= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1452870907; called by muse, mutect2, varscan2
- CA10 | c.189G>A p.G63= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV53342352; called by muse, mutect2, varscan2
- CA3 | c.60C>T p.F20= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV53409971; called by muse, mutect2, varscan2
- CAPN11 | c.945G>A p.L315= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- CARD11 | c.3225C>T p.F1075= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- CBLN4 | c.171C>T p.S57= | Silent (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- CCDC144A | c.336G>A p.R112= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- CCDC158 | c.1518G>A p.Q506= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- CCDC178 | c.819G>A p.L273= | Silent (SNP) | VAF 49/165 reads (30%) | called by muse, mutect2, varscan2
- CCDC180 | c.4776G>A p.S1592= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs771853410, COSV63836808; called by muse, mutect2, varscan2
- CD1A | c.966G>A p.R322= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV56862544; called by muse, mutect2, varscan2
- CD1C | c.201C>T p.F67= | Silent (SNP) | VAF 89/176 reads (51%) | called by muse, mutect2, varscan2
- CDH19 | c.1362C>T p.I454= | Silent (SNP) | VAF 181/572 reads (32%) | catalogued as rs1487852201, COSV100052194; called by muse, mutect2, varscan2
- CELF4 | c.894G>A p.Q298= | Silent (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- CFAP47 | c.4018C>T p.L1340= | Silent (SNP) | VAF 94/169 reads (56%) | called by muse, mutect2, varscan2
- CFTR | c.411C>T p.L137= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- CHGA | c.843G>A p.G281= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- CHGB | c.699G>A p.E233= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV66761637; called by muse, mutect2, varscan2
- CHID1 | c.823C>T p.L275= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- CHST12 | c.66C>T p.I22= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs150285273; called by muse, mutect2, varscan2
- CLEC18B | c.39C>T p.L13= | Silent (SNP) | VAF 50/239 reads (21%) | catalogued as COSV60578410; called by muse, mutect2, varscan2
- CLIC5 | c.189C>T p.T63= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs937376141; called by muse, mutect2, varscan2
- CLSTN3 | c.1866C>T p.S622= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV56939104; called by muse, mutect2, varscan2
- COBL | c.2655G>A p.V885= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- CPA4 | c.558C>T p.I186= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- CPA6 | c.15G>A p.G5= | Silent (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- CRB1 | c.2949G>A p.R983= | Silent (SNP) | VAF 143/295 reads (48%) | called by muse, mutect2, varscan2
- CRMP1 | c.1432C>T p.L478= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, varscan2
371 further variants in this file (0 protein-altering or splice-affecting, 282 silent, 89 other) are not listed here.
